Somatic mutation profile of tumor specimen HCM-BROD-0416-C71-01A (aliquot HCM-BROD-0416-C71-01A-11D-A80U-36) from HCMI case HCM-BROD-0416-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 73.1 years (26,690 days).
Specimen HCM-BROD-0416-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf335b10-8627-40a2-a74c-719d1da8136e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0416-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0416-C71-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63777101-9bc6-441f-b2b8-ecdf098c1214

The open-access MAF lists 111 somatic variants for this specimen: 65 protein-altering or splice-affecting, 41 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 41, Nonsense Mutation 4, Intron 3, Frame Shift Ins 2, Splice Site 1, Frame Shift Del 1, Translation Start Site 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 186/208 reads (89%) | catalogued as rs371387815, CM110128, COSV64288370, COSV64295841; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC099489.1 | c.2488C>T p.R830* | Nonsense Mutation (SNP) | VAF 243/441 reads (55%) | catalogued as rs1213651772; called by muse, mutect2, varscan2
- ADAT3 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 383/1195 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs982080035; called by muse, mutect2, varscan2
- AIRE | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 230/490 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs778067704, COSV52392624; called by muse, mutect2, varscan2
- BAZ2A | c.3507C>G p.F1169L | Missense Mutation (SNP) | VAF 5374/6047 reads (89%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV104385689; called by muse, mutect2, varscan2
- C8orf89 | c.457dup p.S153Kfs*24 | Frame Shift Ins (INS) | VAF 142/318 reads (45%) | catalogued as rs951061763; called by mutect2, varscan2
- CFAP299 | c.337G>A p.V113M | Missense Mutation (SNP) | VAF 125/277 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs149721279; called by muse, mutect2, varscan2
- CHST10 | c.739C>G p.P247A | Missense Mutation (SNP) | VAF 132/700 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.253); catalogued as rs1316111773; called by muse, mutect2
- COL13A1 | c.1916C>T p.A639V (on ENST00000398978 / NM_001130103.2; = p.A567V on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 214/240 reads (89%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs561311848; called by muse, mutect2, varscan2
- CUX1 | c.2611C>T p.Q871* | Nonsense Mutation (SNP) | VAF 313/1059 reads (30%) | catalogued as COSV99473389; called by muse, mutect2, varscan2
- DAW1 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 159/341 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100005737; called by muse, mutect2, varscan2
- DLEC1 | c.2830G>A p.V944I | Missense Mutation (SNP) | VAF 151/367 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as rs201448209; called by muse, mutect2, varscan2
- DNAH10 | c.5233G>A p.A1745T (on ENST00000409039; = p.A1684T on NM_207437.3) | Missense Mutation (SNP) | VAF 228/537 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.104); catalogued as rs1345042500, COSV68996611; called by muse, varscan2
- DNAH8 | c.9505G>A p.D3169N | Missense Mutation (SNP) | VAF 119/252 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV100546826; called by muse, mutect2, varscan2
- EHD3 | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 261/565 reads (46%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.886); catalogued as rs201814896, COSV100434781, COSV59029271; called by muse, mutect2, varscan2
- GRIP1 | c.2881C>T p.R961W (on ENST00000359742 / NM_001379345.1; = p.R909W on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 296/653 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs761580569, COSV99669508; called by muse, mutect2, varscan2
- GRM7 | c.159del p.L54Cfs*46 | Frame Shift Del (DEL) | VAF 290/741 reads (39%) | catalogued as COSV63140513; called by pindel, varscan2
- HELZ2 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 331/1096 reads (30%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs1335466059, COSV64409892; called by muse, mutect2, varscan2
- HRNR | c.7622G>A p.R2541H | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1320025374; called by mutect2, varscan2
- ITGA8 | c.2107C>T p.R703C | Missense Mutation (SNP) | VAF 136/156 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150974250; called by muse, mutect2, varscan2
- KLK7 | c.127T>C p.W43R | Missense Mutation (SNP) | VAF 215/735 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780992617; called by muse, mutect2, varscan2
- KRT34 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 23/855 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs1254149302, COSV67450082; called by muse, mutect2
- LCE3E | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 375/825 reads (45%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1398597048, COSV64232333; called by muse, mutect2, varscan2
- MYNN | c.179A>G p.N60S | Missense Mutation (SNP) | VAF 205/457 reads (45%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as rs773324179; called by muse, varscan2
- NECTIN1 | c.1048G>A p.G350R | Missense Mutation (SNP) | VAF 119/546 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as rs755314137, COSV99871947; called by muse, mutect2, varscan2
- NECTIN2 | c.1130C>T p.T377M | Missense Mutation (SNP) | VAF 248/498 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs540886913; called by muse, mutect2, varscan2
- NKX1-2 | c.335C>A p.P112Q | Missense Mutation (SNP) | VAF 420/448 reads (94%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV71184084; called by muse, mutect2, varscan2
- PIP | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 172/517 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs750884957, COSV52120268; called by muse, mutect2, varscan2
- PNLIP | c.919G>A p.V307I | Missense Mutation (SNP) | VAF 135/148 reads (91%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs773774916, COSV65042392; called by muse, mutect2, varscan2
- PROX1 | c.1243G>A p.V415I | Missense Mutation (SNP) | VAF 343/706 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as rs896925287, COSV54776196, COSV54779311; called by muse, mutect2, varscan2
- SERPINA6 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 227/527 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.084); catalogued as rs748984466; called by muse, mutect2, varscan2
- SHISA7 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 163/442 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.744); catalogued as rs941242224, COSV66244455; called by muse, mutect2, varscan2
- SLC4A1 | c.2473G>A p.V825I | Missense Mutation (SNP) | VAF 149/369 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as rs780297314, COSV52259143; called by muse, mutect2, varscan2
- TEAD1 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 195/439 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs749486560, COSV57563458; called by muse, mutect2, varscan2
- UXS1 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 171/392 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs774228502, COSV51676294; called by muse, mutect2, varscan2
- WIZ | c.4340G>A p.R1447Q (on ENST00000673675 / NM_001371589.1; = p.R352Q on NM_021241.3) | Missense Mutation (SNP) | VAF 191/619 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.107); catalogued as rs372083721, COSV54609315; called by muse, mutect2, varscan2
- ZNF398 | c.1565G>A p.R522H (on ENST00000475153 / NM_170686.3; = p.R351H on NM_020781.4) | Missense Mutation (SNP) | VAF 317/1016 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs1013965037; called by muse, mutect2, varscan2
- ABCF2 | c.609G>C p.K203N | Missense Mutation (SNP) | VAF 246/906 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2
- ANTXR1 | c.1354-1G>A p.X452_splice | Splice Site (SNP) | VAF 106/236 reads (45%) | called by muse, mutect2, varscan2
- ARMC5 | c.715G>C p.V239L | Missense Mutation (SNP) | VAF 307/646 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ASB17 | c.753A>T p.K251N | Missense Mutation (SNP) | VAF 171/369 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CAPN10 | c.407G>C p.C136S | Missense Mutation (SNP) | VAF 223/478 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- COPS6 | c.929A>G p.N310S | Missense Mutation (SNP) | VAF 236/791 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- CRIM1 | c.3036T>A p.D1012E | Missense Mutation (SNP) | VAF 171/382 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CSF1R | c.389C>A p.T130K | Missense Mutation (SNP) | VAF 287/594 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCAF12L2 | c.1158G>T p.R386S | Missense Mutation (SNP) | VAF 173/793 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- DNASE1L3 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 226/435 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EML6 | c.4808C>A p.T1603K | Missense Mutation (SNP) | VAF 230/466 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- FOXQ1 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 221/479 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- G6PC2 | c.484A>C p.I162L | Missense Mutation (SNP) | VAF 165/400 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MTM1 | c.875G>T p.G292V | Missense Mutation (SNP) | VAF 157/352 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR7E24 | c.796G>A p.V266I | Missense Mutation (SNP) | VAF 169/516 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- PKD1L1 | c.2420C>G p.S807C | Missense Mutation (SNP) | VAF 191/628 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNPLA4 | c.175dup p.I59Nfs*5 | Frame Shift Ins (INS) | VAF 172/407 reads (42%) | called by mutect2, pindel, varscan2
- POMGNT1 | c.577C>A p.L193M | Missense Mutation (SNP) | VAF 208/426 reads (49%) | PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- POTEE | c.360G>A p.W120* | Nonsense Mutation (SNP) | VAF 270/653 reads (41%) | called by muse, mutect2, varscan2
- POU3F3 | c.1331A>G p.Q444R | Missense Mutation (SNP) | VAF 274/576 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, varscan2
- SERPINB12 | c.754C>A p.L252I | Missense Mutation (SNP) | VAF 181/390 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYTL1 | c.1256C>A p.P419H (on ENST00000543823; = p.P407H on NM_032872.3) | Missense Mutation (SNP) | VAF 263/549 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- TNFRSF11A | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 222/536 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- UBN1 | c.1930C>G p.Q644E | Missense Mutation (SNP) | VAF 215/516 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- UGT2B10 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 164/328 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- WHRN | c.2422G>A p.G808R | Missense Mutation (SNP) | VAF 168/338 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WIZ | c.5117G>A p.S1706N (on ENST00000673675 / NM_001371589.1; = p.S611N on NM_021241.3) | Missense Mutation (SNP) | VAF 371/1198 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- ZNF512B | c.2551C>G p.R851G | Missense Mutation (SNP) | VAF 372/1247 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- ADD3 | c.1974C>T p.I658= (on ENST00000356080 / NM_001320591.2; = p.I626= on NM_001121.4) | Silent (SNP) | VAF 213/234 reads (91%) | catalogued as rs568629103; called by muse, mutect2, varscan2
- AHNAK2 | c.9339C>T p.V3113= | Silent (SNP) | VAF 366/661 reads (55%) | catalogued as rs747532273, COSV100319352; called by muse, mutect2, varscan2
- AKR1C2 | c.690G>A p.P230= | Silent (SNP) | VAF 87/185 reads (47%) | called by muse, varscan2
- BMX | c.570T>A p.T190= | Silent (SNP) | VAF 306/697 reads (44%) | called by muse, mutect2, varscan2
- CACNA2D2 | c.1302C>T p.D434= | Silent (SNP) | VAF 423/623 reads (68%) | catalogued as rs587671504, COSV99818375; called by muse, mutect2, varscan2
- CACNG3 | c.339G>A p.T113= | Silent (SNP) | VAF 230/476 reads (48%) | catalogued as rs773149814, COSV50089370; called by muse, mutect2, varscan2
- CDH7 | c.1971C>T p.G657= | Silent (SNP) | VAF 204/421 reads (48%) | catalogued as rs772297804; called by muse, mutect2, varscan2
- COPZ2 | c.351C>T p.Y117= | Silent (SNP) | VAF 132/252 reads (52%) | catalogued as rs201805900; called by muse, mutect2, varscan2
- CR2 | c.1653G>A p.T551= | Silent (SNP) | VAF 246/499 reads (49%) | catalogued as rs373293174; called by muse, mutect2, varscan2
- DMXL2 | c.6639G>A p.A2213= | Silent (SNP) | VAF 199/448 reads (44%) | catalogued as rs185024518, COSV51845622; called by muse, mutect2, varscan2
- ERCC6 | c.3870C>T p.A1290= | Silent (SNP) | VAF 124/329 reads (38%) | catalogued as rs769975274; called by muse, mutect2, varscan2
- GRM7 | c.160C>T p.L54= | Silent (SNP) | VAF 335/728 reads (46%) | catalogued as rs1192256982, COSV63175571; called by muse, varscan2
- HTR3B | c.759C>T p.L253= | Silent (SNP) | VAF 181/418 reads (43%) | called by muse, mutect2, varscan2
- JPH2 | c.942C>T p.Y314= | Silent (SNP) | VAF 376/1132 reads (33%) | catalogued as rs1555858688, COSV100881790; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNH1 | c.513C>T p.S171= | Silent (SNP) | VAF 222/473 reads (47%) | catalogued as rs771777021; called by muse, mutect2, varscan2
- KCNH6 | c.2577C>T p.H859= | Silent (SNP) | VAF 302/630 reads (48%) | catalogued as rs547568764; called by muse, varscan2
- KRTAP2-2 | c.45C>T p.Y15= | Silent (SNP) | VAF 97/376 reads (26%) | catalogued as COSV101195330; called by muse, mutect2, varscan2
- LCT | c.4761C>T p.R1587= | Silent (SNP) | VAF 250/479 reads (52%) | catalogued as rs573401319, COSV51545280, COSV51552658; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LOXHD1 | c.3279C>T p.H1093= | Silent (SNP) | VAF 286/682 reads (42%) | catalogued as rs751278435; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- NIBAN2 | c.1788C>T p.S596= | Silent (SNP) | VAF 300/657 reads (46%) | catalogued as rs1463545083; called by muse, mutect2, varscan2
- ODR4 | c.39G>A p.Q13= | Silent (SNP) | VAF 127/271 reads (47%) | called by muse, mutect2, varscan2
- OR5D13 | c.699A>T p.A233= | Silent (SNP) | VAF 280/592 reads (47%) | called by muse, mutect2, varscan2
- P2RY8 | c.888G>A p.A296= | Silent (SNP) | VAF 339/733 reads (46%) | catalogued as COSV67177132; called by muse, mutect2, varscan2
- PABPC5 | c.636C>T p.D212= | Silent (SNP) | VAF 274/561 reads (49%) | catalogued as rs1398599707; called by muse, mutect2, varscan2
- PCDHGA2 | c.1338C>T p.N446= | Silent (SNP) | VAF 305/636 reads (48%) | catalogued as COSV54040582; called by muse, mutect2, varscan2
- PCDHGA3 | c.1056C>T p.L352= | Silent (SNP) | VAF 218/479 reads (46%) | catalogued as rs780908329; called by muse, mutect2, varscan2
- PKD1L1 | c.2421C>T p.S807= | Silent (SNP) | VAF 189/617 reads (31%) | catalogued as rs753912551, COSV56958217; called by muse, mutect2, varscan2
- PLCD3 | c.81G>A p.A27= | Silent (SNP) | VAF 377/789 reads (48%) | called by muse, mutect2, varscan2
- PLEKHN1 | c.1122G>A p.P374= (on ENST00000379409; = p.P322= on NM_032129.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 284/616 reads (46%) | catalogued as rs376185569; called by muse, mutect2, varscan2
- PPP1R2B | c.162G>A p.A54= | Silent (SNP) | VAF 218/479 reads (46%) | called by muse, mutect2, varscan2
- RGL3 | c.690G>A p.A230= | Silent (SNP) | VAF 215/713 reads (30%) | called by muse, mutect2, varscan2
- RIPK4 | c.810G>A p.P270= | Silent (SNP) | VAF 302/571 reads (53%) | catalogued as rs914292273; called by muse, mutect2, varscan2
- SLC38A8 | c.417G>A p.P139= | Silent (SNP) | VAF 196/440 reads (45%) | catalogued as rs201796499; called by muse, mutect2, varscan2
- STK26 | c.21T>A p.A7= | Silent (SNP) | VAF 265/543 reads (49%) | called by muse, mutect2, varscan2
- SYTL1 | c.63G>A p.A21= | Silent (SNP) | VAF 245/523 reads (47%) | catalogued as rs1363074831; called by muse, mutect2, varscan2
- TEAD2 | c.642G>A p.S214= | Silent (SNP) | VAF 202/464 reads (44%) | catalogued as rs758542961; called by muse, mutect2, varscan2
- TGIF2LX | c.177C>T p.A59= | Silent (SNP) | VAF 219/466 reads (47%) | catalogued as COSV99383299, COSV99383406; called by muse, mutect2, varscan2
- TINAG | c.39T>G p.L13= | Silent (SNP) | VAF 124/235 reads (53%) | catalogued as COSV52513253; called by muse, mutect2, varscan2
- ZAR1L | c.573C>T p.D191= | Silent (SNP) | VAF 254/273 reads (93%) | catalogued as rs750925355, COSV61526321; called by muse, mutect2, varscan2
- ZFHX4 | c.1068C>A p.P356= | Silent (SNP) | VAF 234/505 reads (46%) | catalogued as COSV50479574; called by muse, mutect2, varscan2
- ZIC4 | c.234C>T p.F78= | Silent (SNP) | VAF 328/718 reads (46%) | catalogued as rs748665259, COSV101268108; called by muse, varscan2
- DAPL1 | c.226-8793C>T | Intron (SNP) | VAF 117/252 reads (46%) | catalogued as rs769369042; called by muse, mutect2, varscan2
- DCHS2 | n.7604C>T | RNA (SNP) | VAF 228/508 reads (45%) | catalogued as rs748475572, COSV61769754; called by muse, mutect2, varscan2
- GP6 | c.*191C>T | 3'UTR (SNP) | VAF 242/792 reads (31%) | called by muse, mutect2, varscan2
- KIF1A | c.2555+973G>A | Intron (SNP) | VAF 406/798 reads (51%) | catalogued as rs928176653; called by muse, mutect2, varscan2
- OPRM1 | c.1165-10894G>A | Intron (SNP) | VAF 137/341 reads (40%) | catalogued as rs547145262, COSV57823877; called by muse, mutect2, varscan2
